Somatic mutation profile of tumor specimen TARGET-30-PATXXI-01A (aliquot TARGET-30-PATXXI-01A-01D) from TARGET case TARGET-30-PATXXI, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 10.2 years (3,729 days).
Specimen TARGET-30-PATXXI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 518410bc-7525-45d1-bd9f-7540d87e218d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATXXI-10A (Blood Derived Normal), aliquot TARGET-30-PATXXI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97151962-4811-4672-89bf-ac5f7e699e5b

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1B | c.1088G>C p.R363P | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53149185; called by muse, mutect2, varscan2
- ARID2 | c.2055A>G p.P685= | Silent (SNP) | VAF 25/225 reads (11%) | called by muse, mutect2, varscan2
